Somatic mutation profile of tumor specimen C3L-06212-01 (aliquot CPT0424960005) from CPTAC case C3L-06212, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 72.2 years (26,356 days).
Specimen C3L-06212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 741ecf05-c42d-483a-a161-58c82e69ff28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06212-31 (Blood Derived Normal), aliquot CPT0425110005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f71848-259d-428d-a3ef-f47b0ecb949d

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Nonsense Mutation 4, Splice Site 1, RNA 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL5 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 118/2222 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs751869733, COSV100389080; called by muse, mutect2
- ADGRB1 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 553/1176 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV60104404; called by muse, mutect2, varscan2
- ADGRF2 | c.1957G>A p.A653T (on ENST00000296862 / NM_001368115.2; = p.A585T on NM_153839.7) | Missense Mutation (SNP) | VAF 37/790 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771938865, COSV57287952; called by muse, mutect2
- ANK3 | c.13104C>G p.I4368M (on ENST00000280772 / NM_001320874.2; = p.I992M on NM_001149.3) | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV55056963; called by muse, mutect2, varscan2
- ATXN2L | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 538/1313 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs746560568, COSV57364648; called by muse, mutect2, varscan2
- CSNK1E | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 426/1663 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.639); catalogued as rs756435541, COSV63290578; called by muse, mutect2, varscan2
- GRIA4 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 344/396 reads (87%) | catalogued as rs374264327; called by muse, mutect2, varscan2
- KCNA1 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 94/2026 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66838319; called by muse, mutect2
- KLK3 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 495/1115 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs1189692003; called by muse, mutect2, varscan2
- LILRA2 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 536/1266 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV52189795; called by muse, mutect2, varscan2
- MPP3 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 591/658 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV68198542; called by muse, mutect2, varscan2
- MUC16 | c.21401C>A p.P7134Q | Missense Mutation (SNP) | VAF 424/970 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.519); catalogued as COSV104432127; called by muse, varscan2
- NFATC1 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs866000968; called by muse, mutect2
- NMNAT1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as CM127783; called by muse, mutect2, varscan2
- NMUR2 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 336/381 reads (88%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as rs1171670312; called by muse, mutect2, varscan2
- PKD1L2 | c.1040G>T p.S347I | Missense Mutation (SNP) | VAF 492/545 reads (90%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.66); catalogued as rs762146942; called by muse, mutect2, varscan2
- SHANK2 | c.2929T>G p.F977V | Missense Mutation (SNP) | VAF 417/4083 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.523); catalogued as COSV99575604; called by muse, mutect2, varscan2
- ABCA7 | c.2713T>A p.Y905N | Missense Mutation (SNP) | VAF 70/1352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP9A | c.2574T>G p.A858= | Splice Region (SNP) | VAF 279/437 reads (64%) | called by muse, mutect2, varscan2
- BTNL2 | c.188T>A p.V63E | Missense Mutation (SNP) | VAF 443/1117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASKIN2 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 343/921 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCPG1 | c.1210dup p.S404Kfs*3 | Frame Shift Ins (INS) | VAF 46/120 reads (38%) | called by mutect2, pindel, varscan2
- CFAP410 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 299/1358 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DNAJB13 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 963/6125 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- EPS8 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- FAM193A | c.3748A>G p.I1250V (on ENST00000324666 / NM_001256666.1; = p.I1209V on NM_003704.3) | Missense Mutation (SNP) | VAF 334/363 reads (92%) | SIFT tolerated (0.56); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GOLGA8F | c.84A>C p.E28D (on ENST00000526619; = p.E234D on NM_001350920.2) | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GORAB | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 202/770 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, varscan2
- HDAC5 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 485/636 reads (76%) | called by muse, mutect2, varscan2
- IQCN | c.1531G>C p.V511L | Missense Mutation (SNP) | VAF 608/1304 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- IQSEC3 | c.1206C>A p.F402L (on ENST00000538872 / NM_001170738.2; = p.F99L on NM_015232.1) | Missense Mutation (SNP) | VAF 504/2099 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MED15 | c.1256G>C p.R419T | Missense Mutation (SNP) | VAF 40/1544 reads (3%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.02); called by muse, mutect2
- MIA3 | c.2404G>T p.G802* | Nonsense Mutation (SNP) | VAF 15/436 reads (3%) | called by muse, mutect2
- NAP1L2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 431/504 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- OR5P2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 231/1565 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OTUD7A | c.2438C>G p.S813W (on ENST00000307050 / NM_001382637.1; = p.S806W on NM_130901.3) | Missense Mutation (SNP) | VAF 38/997 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2
- PARP8 | c.1069A>T p.I357F | Missense Mutation (SNP) | VAF 458/979 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLK2 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 257/674 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PRPF6 | c.133_138del p.D45_D46del | In Frame Del (DEL) | VAF 405/1137 reads (36%) | called by mutect2, pindel, varscan2
- RBMXL3 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 35/1089 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); called by muse, mutect2
- RPL14 | c.301-1G>A p.X101_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- SPANXN2 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 104/135 reads (77%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TBC1D22A | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 61/2258 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.083); called by muse, mutect2
- TLK2 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 174/877 reads (20%) | called by muse, mutect2, varscan2
- TNK2 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 101/1442 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.616); called by muse, mutect2
- ANO2 | c.39C>G p.R13= (on ENST00000356134 / NM_001278597.3; = p.R17= on NM_001278596.3) | Silent (SNP) | VAF 384/1696 reads (23%) | catalogued as COSV100502005; called by muse, mutect2, varscan2
- CACNG2 | c.579C>T p.V193= | Silent (SNP) | VAF 528/1913 reads (28%) | catalogued as rs149442040; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN1 | c.1755C>G p.A585= | Silent (SNP) | VAF 32/700 reads (5%) | called by muse, mutect2
- GHRL | c.132A>G p.P44= | Silent (SNP) | VAF 715/1106 reads (65%) | called by muse, mutect2, varscan2
- GRM6 | c.2355C>T p.I785= | Silent (SNP) | VAF 514/1808 reads (28%) | catalogued as rs145196229; called by muse, mutect2, varscan2
- LIPC | c.531C>T p.A177= | Silent (SNP) | VAF 186/544 reads (34%) | catalogued as rs761213115, COSV100134833; called by muse, mutect2, varscan2
- LRRC28 | c.963T>C p.P321= | Silent (SNP) | VAF 493/1041 reads (47%) | called by muse, mutect2, varscan2
- MIOS | c.2193A>T p.A731= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- MTMR8 | c.2064A>G p.T688= | Silent (SNP) | VAF 555/592 reads (94%) | called by muse, mutect2, varscan2
- MYH9 | c.591G>C p.S197= | Silent (SNP) | VAF 509/1675 reads (30%) | called by muse, mutect2, varscan2
- NEK5 | c.2010A>G p.A670= | Silent (SNP) | VAF 54/752 reads (7%) | called by muse, mutect2
- OR4C16 | c.597C>T p.S199= | Silent (SNP) | VAF 451/791 reads (57%) | catalogued as rs767167648; called by muse, mutect2, varscan2
- PLEKHD1 | c.588C>T p.A196= | Silent (SNP) | VAF 381/873 reads (44%) | catalogued as rs529299292; called by muse, mutect2, varscan2
- SCUBE1 | c.1830C>G p.A610= | Silent (SNP) | VAF 670/2395 reads (28%) | called by muse, mutect2, varscan2
- SP4 | c.2091T>C p.H697= | Silent (SNP) | VAF 90/121 reads (74%) | catalogued as rs551181654; called by muse, mutect2, varscan2
- TMPRSS2 | c.1245C>T p.V415= | Silent (SNP) | VAF 362/1187 reads (30%) | called by muse, mutect2, varscan2
- AL449403.2 | n.242C>T | RNA (SNP) | VAF 288/739 reads (39%) | called by muse, mutect2, varscan2
